Somatic mutation profile of tumor specimen C3N-01200-02 (aliquot CPT0075130009) from CPTAC case C3N-01200, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.3 years (20,550 days).
Specimen C3N-01200-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da2548d8-3202-4617-a2d0-19e61cfa34cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01200-71 (Blood Derived Normal), aliquot CPT0075240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c76a858f-0d81-4966-a2f1-c247fbac1009

The open-access MAF lists 80 somatic variants for this specimen: 44 protein-altering or splice-affecting, 17 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Intron 11, Frame Shift Del 5, 3'UTR 5, Frame Shift Ins 3, In Frame Del 3, RNA 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.758dup p.T254Dfs*30 | Frame Shift Ins (INS) | VAF 86/323 reads (27%) | catalogued as rs1553645591; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP1A3 | c.1778C>G p.S593C (on ENST00000545399 / NM_001256214.2; = p.S580C on NM_152296.5) | Missense Mutation (SNP) | VAF 65/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57487252; called by muse, mutect2, varscan2
- BTBD3 | c.1207A>C p.K403Q | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs759996580; called by muse, mutect2, varscan2
- EEA1 | c.1759C>A p.Q587K | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs1172307888; called by muse, mutect2, varscan2
- GLRA3 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56864626; called by muse, mutect2, varscan2
- MBP | c.562C>T p.R188W (on ENST00000355994 / NM_001025101.2; = p.R55W on NM_002385.3) | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs766571087; called by muse, mutect2, varscan2
- MICAL2 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV56320093; called by muse, mutect2, varscan2
- PCDHGA4 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 27/219 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as rs746094461, COSV53925110; called by muse, mutect2, varscan2
- SLC19A1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs776173955, COSV60756989; called by muse, mutect2, varscan2
- USP12 | c.500C>G p.P167R | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV99997488; called by muse, mutect2
- AK2 | c.139A>G p.T47A (on ENST00000354858; = p.T89A on NM_001625.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/355 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- CASD1 | c.2264T>C p.I755T | Missense Mutation (SNP) | VAF 42/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CBX3 | c.448T>A p.L150M | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2
- CSMD3 | c.9249T>A p.D3083E (on ENST00000297405 / NM_001363185.1; = p.D2914E on NM_052900.3) | Missense Mutation (SNP) | VAF 61/434 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF7 | c.276_284del p.D93_L95del | In Frame Del (DEL) | VAF 18/142 reads (13%) | called by mutect2, pindel
- DNAH11 | c.11714del p.G3905Vfs*12 | Frame Shift Del (DEL) | VAF 21/126 reads (17%) | called by mutect2, pindel, varscan2
- DNAH5 | c.7391del p.G2464Afs*2 | Frame Shift Del (DEL) | VAF 34/200 reads (17%) | called by mutect2, pindel, varscan2
- ELL2 | c.125T>C p.L42P | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2
- FOXB2 | c.599dup p.Q201Afs*73 | Frame Shift Ins (INS) | VAF 30/157 reads (19%) | called by mutect2, pindel, varscan2
- GRIPAP1 | c.380_406del p.A127_G135del | In Frame Del (DEL) | VAF 10/111 reads (9%) | called by mutect2, pindel
- HAS3 | c.1227T>G p.I409M | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- KCNG2 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- KIFAP3 | c.2088G>T p.E696D | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- LAMC3 | c.2048T>G p.F683C | Missense Mutation (SNP) | VAF 48/501 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LCE3A | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MSH3 | c.857C>A p.P286H | Missense Mutation (SNP) | VAF 33/376 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTMR3 | c.2322del p.L775Sfs*24 | Frame Shift Del (DEL) | VAF 44/320 reads (14%) | called by mutect2, pindel, varscan2
- OR9Q2 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- PKD1 | c.6186G>T p.Q2062H | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- POLE | c.1399T>A p.Y467N | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RALGAPA1 | c.5306T>G p.L1769R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- REM1 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SALL3 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.109); called by muse, varscan2
- SCAMP3 | c.848C>A p.A283D | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SMARCD2 | c.1534T>A p.F512I | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2
- SNX5 | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SPANXN5 | c.154_156del p.L52del | In Frame Del (DEL) | VAF 19/117 reads (16%) | called by mutect2, pindel, varscan2
- SPART | c.783del p.L262* | Frame Shift Del (DEL) | VAF 24/171 reads (14%) | called by mutect2, pindel, varscan2
- SPATS2 | c.235A>C p.K79Q | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VHL | c.610_614del p.E204Hfs*50 | Frame Shift Del (DEL) | VAF 86/356 reads (24%) | called by mutect2, pindel, varscan2
- VPS35 | c.1499_1500dup p.E501Lfs*9 | Frame Shift Ins (INS) | VAF 32/332 reads (10%) | called by mutect2, pindel
- WDR6 | c.3121C>T p.P1041S | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF256 | c.1369C>T p.H457Y | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF470 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- ADCY6 | c.2322C>A p.A774= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as rs1362941438; called by muse, mutect2, varscan2
- AHNAK | c.6627A>T p.V2209= | Silent (SNP) | VAF 68/403 reads (17%) | called by muse, mutect2, varscan2
- AL162231.1 | c.163C>T p.L55= | Silent (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- CDK11B | c.1002G>A p.E334= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs1279885928; called by muse, mutect2, varscan2
- CENPE | c.2013A>G p.L671= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV99477122; called by muse, mutect2, varscan2
- IFIH1 | c.2532G>A p.E844= | Silent (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2, varscan2
- KCNG2 | c.1254G>A p.Q418= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- MFSD6 | c.1326C>T p.L442= | Silent (SNP) | VAF 52/179 reads (29%) | called by muse, mutect2, varscan2
- MS4A4E | c.126G>A p.R42= | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs267603050; called by muse, mutect2, varscan2
- NOTCH3 | c.1335G>A p.T445= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as rs568403807, COSV54650413; called by muse, mutect2
- NPY5R | c.1254T>C p.C418= | Silent (SNP) | VAF 30/157 reads (19%) | called by muse, mutect2, varscan2
- PAK4 | c.939C>T p.D313= | Silent (SNP) | VAF 56/305 reads (18%) | catalogued as rs369018322; called by muse, mutect2
- PLEKHA4 | c.441G>T p.A147= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs1404611123; called by muse, mutect2, varscan2
- PLXDC2 | c.1395C>A p.L465= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as COSV65904134; called by muse, mutect2, varscan2
- TMEM181 | c.1344G>A p.L448= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2
- TTN | c.84165A>C p.T28055= (on ENST00000591111; = p.T20631= on NM_003319.4) | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- VEZF1 | c.348C>A p.I116= | Silent (SNP) | VAF 35/174 reads (20%) | called by muse, mutect2, varscan2
- AC106741.1 | c.*39G>T | 3'UTR (SNP) | VAF 23/141 reads (16%) | catalogued as rs1339151046; called by muse, mutect2, varscan2
- CD320 | c.*205G>C | 3'UTR (SNP) | VAF 49/189 reads (26%) | called by muse, mutect2, varscan2
- FAM193B | c.1076+18A>C | Intron (SNP) | VAF 28/233 reads (12%) | called by muse, mutect2, varscan2
- FGFR4 | c.1057+165_1057+166del | Intron (DEL) | VAF 58/320 reads (18%) | called by pindel, varscan2
- FOXP2 | c.*2787_*2788del | 3'UTR (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- HBD | c.-29+230G>C | Intron (SNP) | VAF 33/219 reads (15%) | called by muse, mutect2, varscan2
- LINC02694 | n.107A>C | RNA (SNP) | VAF 19/102 reads (19%) | called by muse, mutect2, varscan2
- MT1G | c.97+82_97+84del | Intron (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- PLA2G6 | c.210-29G>T | Intron (SNP) | VAF 52/306 reads (17%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34158773 C>T | 5'Flank (SNP) | VAF 11/113 reads (10%) | catalogued as rs772284609; called by muse, mutect2
- RPL4 | c.-24G>A | 5'UTR (SNP) | VAF 24/108 reads (22%) | catalogued as rs371027636; called by muse, mutect2, varscan2
- RTN4R | c.23-414C>A | Intron (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- SLC11A2 | c.*1609T>C | 3'UTR (SNP) | VAF 19/123 reads (15%) | called by muse, mutect2, varscan2
- SLC2A1 | c.868-50del | Intron (DEL) | VAF 39/215 reads (18%) | called by mutect2, pindel, varscan2
- TMEM134 | c.329+28C>T | Intron (SNP) | VAF 33/213 reads (15%) | catalogued as rs201248558; called by muse, mutect2, varscan2
- TMEM258 | c.3+19G>T | Intron (SNP) | VAF 41/238 reads (17%) | called by muse, mutect2, varscan2
- USP32P3 | n.3271+886C>A | Intron (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- VAPB | c.*4774A>G | 3'UTR (SNP) | VAF 47/292 reads (16%) | catalogued as COSV55666798; called by muse, mutect2, varscan2
- ZEB1 | c.58+43636G>T | Intron (SNP) | VAF 36/167 reads (22%) | called by muse, mutect2, varscan2
